Somatic mutation profile of tumor specimen 0DGMHP from CCDI case PBBTLN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 5.8 years (2,107 days).
Specimen 0DGMHP: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac3c886d-0604-4a34-9d82-a6fca2f2662b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGMI0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4f1dd1a-535a-441f-b855-6639ae6824fd

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 3, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRRC2C | c.2981G>A p.R994H (on ENST00000367742; = p.R992H on NM_015172.4) | Missense Mutation (SNP) | VAF 232/516 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs368272659; called by muse, mutect2, varscan2
- PTPRZ1 | c.2705C>T p.T902M | Missense Mutation (SNP) | VAF 150/409 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.054); catalogued as rs1307600967; called by muse, mutect2, varscan2
- CCDC168 | c.4588C>T p.Q1530* | Nonsense Mutation (SNP) | VAF 14/357 reads (4%) | called by muse, mutect2
- CREB3L1 | c.390G>T p.Q130H | Missense Mutation (SNP) | VAF 144/372 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 28/750 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- ZFPM2 | c.1545G>C p.E515D | Missense Mutation (SNP) | VAF 36/524 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 36/578 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- FGD5 | c.1320G>A p.A440= | Silent (SNP) | VAF 94/278 reads (34%) | catalogued as rs762200401; called by muse, mutect2, varscan2
- CCDC149 | c.63+17713T>G | Intron (SNP) | VAF 19/207 reads (9%) | called by muse, varscan2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 12/100 reads (12%) | called by muse, varscan2
- ZNF24 | c.569-67A>T | Intron (SNP) | VAF 15/139 reads (11%) | called by muse, varscan2
